Somatic mutation profile of tumor specimen TCGA-78-7163-01A (aliquot TCGA-78-7163-01A-12D-2063-08) from TCGA case TCGA-78-7163, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 60.2 years (22,002 days).
Specimen TCGA-78-7163-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8b8bf7b-f10d-46b3-af06-1521640924f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7163-11A (Solid Tissue Normal), aliquot TCGA-78-7163-11A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09287c06-1227-471d-856c-157ef1266de9

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5, Nonsense Mutation 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARPC2 | c.235G>T p.V79L | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV55283895; called by muse, mutect2, varscan2
- ATXN2 | c.2940T>G p.P980= (on ENST00000550104; = p.P820= on NM_002973.4) | Splice Region (SNP) | VAF 50/154 reads (32%) | catalogued as COSV66481975; called by muse, mutect2, varscan2
- CSMD3 | c.5865C>G p.Y1955* (on ENST00000297405 / NM_001363185.1; = p.Y1851* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as COSV52129689; called by muse, mutect2, varscan2
- DOCK10 | c.6496C>G p.R2166G | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV51359299; called by muse, mutect2, varscan2
- FOXRED2 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1191848711, COSV53399197; called by muse, mutect2, varscan2
- GRIK5 | c.1056G>A p.M352I | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.365); catalogued as COSV53476177; called by muse, mutect2, varscan2
- IGHD | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs376901676, COSV101162941, COSV66654942; called by muse, mutect2, varscan2
- LPA | c.4420A>C p.T1474P | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV60298861; called by muse, mutect2
- OR51T1 | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59024284; called by muse, mutect2
- PLA2G4F | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs142310375; called by muse, mutect2
- REL | c.1319C>T p.S440L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.32); catalogued as rs144119768, COSV54363001; called by muse, mutect2, varscan2
- RIPOR3 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1283653254, COSV50386415; called by muse, mutect2
- RPS6KA3 | c.1816G>A p.V606I | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as COSV65387224; called by muse, mutect2, varscan2
- VSIG1 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1307680952, COSV54258220; called by muse, mutect2
- SCN8A | c.5043dup p.I1682Yfs*3 | Frame Shift Ins (INS) | VAF 26/117 reads (22%) | called by mutect2, pindel, varscan2
- ARHGAP5 | c.1221T>C p.T407= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as COSV61534456; called by muse, mutect2, varscan2
- GRIK3 | c.519G>C p.R173= | Silent (SNP) | VAF 75/309 reads (24%) | catalogued as COSV66136897; called by muse, mutect2, varscan2
- IGHG1 | c.3C>T p.A1= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs17850093; called by muse, mutect2
- TMEM63B | c.9C>G p.P3= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV52477515, COSV99441920; called by muse, mutect2, varscan2
- UNC45A | c.447G>A p.T149= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as rs773418072, COSV67816025; called by muse, mutect2, varscan2
